TCGA case TCGA-ZP-A9D1 — Liver Hepatocellular Carcinoma (TCGA-LIHC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts; Tissue source site: Medical College of Wisconsin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/447ac9e3-0533-461a-bc92-906a7b2180c3

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 56 years; Vital status: Alive.

Diagnoses (2)
1. Hepatocellular carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8170/3; ICD-10 code: C22.0; Tissue or organ of origin: Liver; Site of resection or biopsy: Liver; Classification of tumor: primary; Age at diagnosis: 56.4 years (20,584 days); Year of diagnosis: 2012; AJCC staging edition: 7th; AJCC pathologic T: T1; AJCC pathologic N: NX; AJCC pathologic M: MX; Tumor grade: G2; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 21 days; Child pugh classification: A; Ishak fibrosis score: 5 - Nodular Formation and Incomplete Cirrhosis.
   Pathology details: Consistent pathology review: Yes; Vascular invasion present: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Ablation or Embolization, NOS; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Clear cell carcinoma: ICD-O-3 morphology code: 8310/3; Tissue or organ of origin: Kidney, NOS; Laterality: Right; Classification of tumor: Prior primary; Age at diagnosis: 49.1 years (17,916 days); Days to diagnosis: -2,668 days (-7.3 years); AJCC staging edition: 6th; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage I.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -2,668 days (-7.3 years); Treatment anatomic sites: Kidney.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 21 days; Disease response: Tumor Free.
- ECOG performance status: 0.

Molecular and laboratory tests
- Prothrombin Time 12 Seconds [Blood test normal range lower: 9.6; Blood test normal range upper: 12.6].
- Alpha Fetoprotein 8 ng/mL [Blood test normal range lower: 0; Blood test normal range upper: 8].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 130 kg; Height: 170 cm; BMI: 45.
- Timepoint category: Prior to Diagnosis; Risk factors: Nonalcoholic Fatty Liver Disease.

Family history
- Relatives with cancer history count: 1.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-ZP-A9D1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 70 mg.
  Slide TCGA-ZP-A9D1-01A-01-TS1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 25; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-ZP-A9D1-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-ZP-A9D1-10B: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Histologic diagnosis: Hepatocellular Carcinoma; Definitive surgical procedure: Segmentectomy, Single; New tumor event diagnosis indicator: No.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Kidney; Other malignancy histological type: Kidney Clear Cell Renal Carcinoma.
- Other malignancy form, Surgery: Other malignancy surgery type: Right Partial Nephrectomy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 21 days; disease-specific survival: no event (censored), 21 days; disease-free interval: no event (censored), 21 days; progression-free interval: no event (censored), 21 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-ZP-A9D1-01A-11D-A381-01): tumor purity 0.47, ploidy 2.97, whole-genome doublings 1.
